CCDI case PBCLNW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/e3d3f54a-74cc-4386-9e06-9d95396d3731

Demographics
Sex at birth: male; Race: white.

Biospecimens (2 samples)
- Sample 0DUUPT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUUQ9: Tissue type: Tumor; Specimen type: Solid Tissue.
